Gene-level copy-number profile of tumor specimen C3N-03092-01 from CPTAC case C3N-03092, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-03092-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f13ff2a-d5c7-4eb7-b288-da878293743f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03092-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/c8a520ad-1e99-4095-bf2e-18965c86e669

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 4,147; copy number 2: 29,718; copy number 3: 14,819; copy number 4: 5,390; copy number 5: 2,011; copy number 6: 2,161; copy number 7: 2; copy number 8: 125; copy number 12: 6.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:12,333,644–12,425,000, 10 genes: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P.
- chr16:921,033–986,979, 4 genes (within-gene range 0–2): LMF1-AS1, AC009041.3, CEROX1, SOX8.
- chr16:30,267,553–30,335,374, 1 gene: SMG1P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,301 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:112,921,205–112,975,103, 1 gene, copy number 6: CD200R1.
- chr3:118,004,819–118,810,836, 2 genes, copy number 5: AC068633.1, AC068633.2.
- chr3:148,850,933–198,123,232, 872 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr4:51,843,000–51,978,372, 4 genes, copy number 5: DCUN1D4, DUTP7, AC027271.1, AC104784.1.
- chr5:58,198–45,895,970, 679 genes, copy number 6 (broad region; genes not listed).
- chr5:160,563,120–160,852,214, 1 gene, copy number 7 (within-gene range 4–7): ATP10B.
- chr5:160,685,351–160,692,889, 1 gene, copy number 7: AC011363.1.
- chr5:162,424,042–164,234,097, 16 genes, copy number 5–12: AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2.
- chr5:173,056,352–178,166,562, 142 genes, copy number 5 (broad region; genes not listed).
- chr7:57,828,331–159,233,377, 1,901 genes, copy number 5–6 (broad region; genes not listed).
- chr8:130,595,299–135,456,952, 64 genes, copy number 5 (broad region; genes not listed).
- chr11:123,629,187–135,075,908, 240 genes, copy number 5 (broad region; genes not listed).
- chr12:12,310–1,647,212, 35 genes, copy number 5: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14.
- chr17:27,237,859–30,965,500, 216 genes, copy number 5 (broad region; genes not listed).
- chr17:32,492,522–32,877,177, 2 genes, copy number 5 (within-gene range 3–5): MYO1D, AC079336.5.
- chr17:32,518,953–34,639,318, 43 genes, copy number 5 (within-gene range 3–5): AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1.
- chr17:55,264,960–55,872,939, 11 genes, copy number 5: HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr19:43,766,533–45,038,198, 71 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
